Gene-level copy-number profile of tumor specimen ALCH-B2RN-TTP1-A from ALCHEMIST case ALCH-B2RN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.9 years (20,060 days).
Specimen ALCH-B2RN-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 30b90532-7d5f-4f17-8bdd-ab76b7bb1085.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2RN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/cf4f32df-157e-4000-8301-e84da344f8db

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 29; copy number 2: 57,861; copy number 3: 301; copy number 4: 101; copy number 5: 32; copy number 6: 48; copy number 7: 22; copy number 8: 6; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 109 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:39,983,793–40,106,611, 1 gene, copy number 5 (within-gene range 2–5): AL772307.1.
- chr9:40,105,822–40,106,527, 1 gene, copy number 5: AL773545.3.
- chr12:63,271,404–63,823,895, 10 genes, copy number 6: HNRNPA1P69, AC026116.1, DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4.
- chr12:64,222,337–64,397,065, 1 gene, copy number 7 (within-gene range 4–7): AC012158.1.
- chr12:64,264,762–68,451,663, 91 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr12:69,239,569–69,285,485, 3 genes, copy number 7: CPSF6, MIR1279, C1GALT1P1.
- chr22:21,370,064–21,371,945, 1 gene, copy number 15: AP000552.1.
- chr22:21,466,423–21,471,269, 1 gene, copy number 7: TMEM191C.

Autosomal genes at a single copy (total copy number 1): 29. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
